TCGA case TCGA-AA-3667 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d651f9ba-8746-46c4-852c-6c2992c7d10e

Demographics
Sex at birth: female; Country of residence at enrollment: Germany; Age at index: 36 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.9; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Sigmoid colon; Classification of tumor: primary; Age at diagnosis: 36.4 years (13,302 days); Year of diagnosis: 2005; AJCC staging edition: 5th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 426 days (1.2 years).
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 22; Lymphatic invasion present: No; Vascular invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; Disease response: With Tumor.
- Days to follow up: 426 days (1.2 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 0.45 ng/mL.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AA-3667-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.6; Intermediate dimension: 0.6; Shortest dimension: 0.4.
  Slide TCGA-AA-3667-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-AA-3667-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-AA-3667-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Samples TCGA-AA-3667-10A, TCGA-AA-3667-10B (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; CEA level pretreatment: 0.45; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Mismatch rep proteins tested by IHC: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 426 days; disease-specific survival: no event (censored), 426 days; disease-free interval: no event (censored), 426 days; progression-free interval: no event (censored), 426 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AA-3667-01A-01D-0903-01): tumor purity 0.84, ploidy 2.23, whole-genome doublings 0.
